Surgical pathology report (de-identified scan), TCGA case TCGA-CV-6960, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-6960-01A (Primary Tumor).

[page 1 of 2]
SUPPLEMENTAL REPORT

DIAGNOSIS:

- (A) TOTAL LARYNGOGLOSSECTOMY:
INVASIVE POORLY DIFFERENTIATED SQUAMOUS CARCINOMA SUPERFICIALLY INVOLVING BONE.

Entire report and diagnosis completed by:
Report released by:

DIAGNOSIS

- (A) TOTAL LARYNGOGLOSSECTOMY:
INVASIVE POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA OF BASE OF TONGUE (5.5 CM) EXTENDING TO LARYNX INVOLVING ANTERIOR DEEP MARGIN, MUCOSAL AND TRACHEAL MARGINS FREE OF TUMOR.
Ten lymph nodes, no tumor present, (left neck nodes).
Twelve lymph nodes, no tumor present (right neck nodes).
Submandibular glands, right and left.
- (B) NEW ANTERIOR SOFT TISSUE MARGIN:
Smooth muscle, no tumor present.
- (C) SOFT TISSUE ANTERIOR FLOOR OF MOUTH:
INVASIVE POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA IN FIBROMUSCULAR TISSUE.

Entire report and diagnosis completed by:
Report released by:

GROSS DESCRIPTION

(A) TOTAL LARYNGOGLOSSECTOMY - A total laryngectomy specimen that includes the larynx (10 x 8 x 6 cm), attached tongue (8 x 6 x 5 cm) and attached bilateral salivary glands, each (3.5 x 2.5 x 2.5 cm).

[page 2 of 2]
[REDACTED]

Located at the base of tongue and epiglottis, is an ulcerated mass (5.5 x 5.0 cm and 4.5 cm in depth). The mass involves the epiglottis, base of tongue, pre-epiglottic space and pyriform sinus. The tumor grossly extends to the anterior intrinsic muscle margins. The tumor is present in supraglottic space and extends inferiorly to 1 cm superior to true vocal cords. The lesion grossly involves both right and lateral aspects of the supraglottic space. However, the glottic space and infraglottic spaces are not involved. The tumor anteriorly approaches the hyoid bone.

The true and false vocal cords, the trachea and salivary glands are unremarkable. Multiple lymph nodes are retrieved (ranging from 1.5 to 0.2 cm in greatest dimension).

The tip of tongue is granular.

INK CODE: Blue - the floor of mouth margin and mucosal margin. Green - the anterior soft tissue margin.

SECTION CODE: A1, left lateral margin, en face, frozen section examination; A2, right lateral mucosal margin, en face, frozen section examination; A3, anterior intrinsic muscle (perpendicular), frozen section examination; A4, additional left lateral mucosal margin; A5, additional right lateral mucosal margin; A6, inferior mucosal margin; A7 and A8, tumor at the base of tongue; A9, tumor in relation to right false vocal cord; A10, true vocal cord, right side; A11 and A12, tumor in relation to left false vocal cord and true vocal cord; A13, tracheal margin; A14, anterior soft tissue margin; A15, posterior commissure; A16, left aryepiglottis; A17, right aryepiglottis; A18, left salivary gland and tumor; A19, right salivary gland; A20, one lymph node from left side; A21, one lymph node from left side; A22, multiple lymph nodes from left side; A23, one lymph node from right side; A24, multiple lymph nodes, right side; A25, one lymph node, right side; A26, two lymph nodes, right side; A27, one lymph node, right side; A28, one lymph node from right side; A29, one lymph node from left side; A30, one lymph node from left side; A31, section from tumor and tongue; A32, section from tip of the tongue (granular area). [REDACTED]

Tissue is sent to bone lab for decalcification and additional sections.

(B) NEW ANTERIOR SOFT TISSUE MARGIN - A fragment of dark red soft tissue (1.7 x 1.5 x 0.9 cm). Bisected and entirely submitted for frozen section in B1 and B2. [REDACTED]

*FS/DX: SMOOTH MUSCLE, NO TUMOR PRESENT. [REDACTED]

(C) SOFT TISSUE ANTERIOR FLOOR OF MOUTH - Multiple irregular in shape portions of tan-purple muscle and soft tissue (5.0 x 4.0 x 2.0 cm in aggregate). No orientation is provided. Representative sections are submitted in C1-C4. [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file eaba2ef5-778e-4473-93c0-5195fb4133ae (TCGA-CV-6960.EBA4850E-B096-4571-81E5-4217391A4119.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).